Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A3MG, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A3MG-01A (Primary Tumor).

[page 1 of 6]
1CD-0-3
carcinoma, papillary urothelial 8/30/3
Site: bladder, NOS C67.9
hw 1/2/12

CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. **Histological pattern:**

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse				Streaming			
Mosaic		X		Scoriform			
Necrosis			X	Fibrosis			
Lymphocytic Infiltration			X	Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized			X	Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Pseudopodia/Calcification			

2. **Cellular features:**

Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamous Cell		X		Glandular cell				Round Cell				Large Cell			
Spindle Cell		X		Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pewl				Gland formation				Myoblast				Plasma Cell			

Otherwise Specified: D1 30% D2 70% D3 50% D4 70%.

2. Cellular Differentiation:

Well	Moderately	Poor
✓		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell		✓		
Mitotic Activity		✓		
Nuclear Grade				

Histological Diagnosis: Papillary Transitional Cell Carcinoma, G1

Comments: _____

Date: _____

Director, Research Pathology

* (INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

HPV Discrepancy		✓
Case is (Surre):		✓
Reviewed: _____		✓

UID:DBIF9F51-DFAE-4A1E-9976-E63EE782149C

[page 2 of 6]
Microscopic Description

Histological Pattern									
Cell Distribution					Structural Pattern				
	+	-				+	-		
Diffuse		×			Streaming				
Mosaic					Storiform				
Necrosis					Fibrosis				
Lymphocytic Infiltration					Palisading				
Vascular Invasion					Cystic Degeneration				
Clusterized					Bleeding				
Alveolar Formation					Myxoid Change				
Indian File					Psammoma/Calcification				

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		×		Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation: Well ☒ Moderate ☐ Poor ☐

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell		✓		
Mitotic Activity		✓		

Nuclear Grade: ☐ ☒ ☐ ☐

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: papillary carcinoma of the bladder
(moderately differentiated) Grade: 2

Comments:

Principal Investigator

Pathologist

Date

[page 3 of 6]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____
Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	0	4	0			4	0
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Uterine bladder tumor	8 x 6 x 3 cm		cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0 Stage: II			
Notes:			

[page 4 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumor was found in the U. bladder.	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Urinary bladder cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2a N0 M0 Stage: II		

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Resection of total U. bladder		
Primary Tumor		
Organ	Detailed Location	Size
Urinary bladder tumor		x x cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T2 N0 M0 Stage: II		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 5 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies	
	Date of Last Menses	# of Live Births	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other:			☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	20 (yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:	
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:	
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:	
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:	
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:	
B/T Cell Markers:					

[page 6 of 6]
Clinical Case Report

(For Collection of Cancerous Tissue)

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator _____

Signature _____

Date _____

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	Blood Pressure	Heart Rate
		☐ Divorced ☐ Widow		
☒ Male ☐ Female			138	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Fever, fatigue, blood in the urine
Symptoms: weakness; weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

Source: NCI Genomic Data Commons file a2df5b63-1b87-4e16-bd7b-ccc585a2ef82 (TCGA-CF-A3MG.DB1F9F51-DFAE-4A1E-9976-E63EE782149C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).